Gene-level copy-number profile of tumor specimen ALCH-AE7W-TTP1-A from ALCHEMIST case ALCH-AE7W, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 69.3 years (25,308 days).
Specimen ALCH-AE7W-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 6b2e6a45-74c4-48aa-b31f-266a6c3780a1.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE7W-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,219 have no estimate.
https://portal.gdc.cancer.gov/files/34829cd2-cdfd-408a-8e21-db00ba48e20b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 13,579; copy number 2: 42,982; copy number 3: 981; copy number 4: 846; copy number 5: 8.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:44,011,882–44,038,978, 1 gene (within-gene range 0–1): AC017116.2.
- chr7:44,026,951–44,041,892, 1 gene (within-gene range 0–2): RASA4CP.
- chr9:138,129,399–138,129,526, 1 gene: AL591424.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:136,658,856–136,672,678, 2 genes, copy number 5 (within-gene range 3–5): EGFL7, MIR126.
- chr9:136,844,415–136,860,799, 3 genes, copy number 5 (within-gene range 3–5): AJM1, PHPT1, MAMDC4.
- chr15:92,883,413–92,949,230, 1 gene, copy number 5 (within-gene range 2–5): AC013394.1.
- chr15:92,904,399–92,904,475, 1 gene, copy number 5 (within-gene range 2–5): MIR3175.
- chr20:62,952,707–62,969,585, 1 gene, copy number 5: SLC17A9.

Autosomal genes at a single copy (total copy number 1): 11,240. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
